Somatic mutation profile of tumor specimen MP2PRT-PAUULK-TMP1-A (aliquot MP2PRT-PAUULK-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAUULK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,789 days).
Specimen MP2PRT-PAUULK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d88cb6a2-4f5b-4561-96c8-b53c31d5813c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUULK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUULK-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fd6aac4-ec5c-4f05-a373-2cb690970ab5

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1775T>G p.V592G | Missense Mutation (SNP) | VAF 135/315 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV54051432, COSV54058572, COSV54074139; called by muse, mutect2, varscan2
- NLRP4 | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 152/354 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.28); catalogued as rs766831042, COSV100017269; called by muse, mutect2, varscan2
- PIGQ | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 283/634 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs761862021; called by muse, mutect2, varscan2
- PKHD1L1 | c.3845G>A p.C1282Y | Missense Mutation (SNP) | VAF 191/452 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs763808526; called by muse, mutect2, varscan2
- ZFHX4 | c.3797C>T p.T1266M | Missense Mutation (SNP) | VAF 185/365 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs763149017, COSV51467227; called by muse, mutect2, varscan2
- GLI3 | c.3204C>A p.S1068R | Missense Mutation (SNP) | VAF 241/436 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM6A | c.443_443+1insTGGA p.W148Cfs*5 | Frame Shift Ins (INS) | VAF 93/101 reads (92%) | called by mutect2, pindel, varscan2
- ADGRL2 | c.4194G>A p.R1398= (on ENST00000370717 / NM_001366005.1; = p.R1342= on NM_012302.4) | Silent (SNP) | VAF 32/448 reads (7%) | catalogued as COSV54675567; called by muse, mutect2
- IDH1 | c.825C>T p.D275= | Silent (SNP) | VAF 105/340 reads (31%) | catalogued as rs374900600; called by muse, mutect2, varscan2
- IRX2 | c.669C>T p.H223= | Silent (SNP) | VAF 201/435 reads (46%) | catalogued as rs753207229; called by muse, mutect2, varscan2
- KRT86 | c.1047G>A p.A349= | Silent (SNP) | VAF 161/381 reads (42%) | catalogued as rs369312934; called by muse, mutect2, varscan2
- NLGN2 | c.345C>T p.P115= | Silent (SNP) | VAF 265/618 reads (43%) | catalogued as COSV56658574, COSV56658676; called by muse, mutect2, varscan2
